Somatic mutation profile of tumor specimen TCGA-VQ-A91U-01A (aliquot TCGA-VQ-A91U-01A-11D-A410-08) from TCGA case TCGA-VQ-A91U, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 78.8 years (28,791 days).
Specimen TCGA-VQ-A91U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fbc0deb-b855-49f0-9df5-79c5c8f73b71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91U-10A (Blood Derived Normal), aliquot TCGA-VQ-A91U-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae5d9065-2210-4386-950d-df80bb046066

The open-access MAF lists 158 somatic variants for this specimen: 115 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 41, Nonsense Mutation 9, Frame Shift Del 4, Splice Region 3, Splice Site 3, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH15 | c.594G>A p.P198= | Splice Region (SNP) | VAF 25/151 reads (17%) | catalogued as rs368308772; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 30/51 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.5562G>A p.Q1854= (on ENST00000272895 / NM_173076.3; = p.Q1536= on NM_015657.3) | Splice Region (SNP) | VAF 22/124 reads (18%) | catalogued as rs1459045233, COSV99791358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD50 | c.932A>G p.D311G | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs750924375, COSV101539012; called by muse, mutect2, varscan2
- APC | c.1685C>T p.T562M | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs587783034, COSV57339803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID4B | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.432); catalogued as COSV99936106; called by muse, mutect2, varscan2
- BRINP1 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56297647, COSV99776485; called by muse, mutect2, varscan2
- BRINP2 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100838259, COSV64178829; called by muse, mutect2
- C2orf16 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs770708739, COSV101284409; called by muse, mutect2, varscan2
- CABIN1 | c.5008-1G>A p.X1670_splice | Splice Site (SNP) | VAF 50/209 reads (24%) | catalogued as COSV99573796; called by muse, mutect2, varscan2
- CCSER2 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs774665507, COSV99826336; called by muse, mutect2, varscan2
- CD2AP | c.1621T>C p.Y541H | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.143); catalogued as COSV100830590; called by muse, mutect2
- CD44 | c.1077G>C p.W359C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV99555945; called by muse, mutect2, varscan2
- CDH9 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99141309, COSV99145337; called by muse, mutect2, varscan2
- CNTLN | c.2452C>T p.R818* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs754809834, COSV52072643; called by muse, mutect2, varscan2
- CNTN5 | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201496247, COSV54293853; called by muse, mutect2, varscan2
- COBL | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs370348190; called by muse, mutect2, varscan2
- COL21A1 | c.2273G>A p.G758D | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264603796, COSV99779690; called by muse, mutect2, varscan2
- COLEC12 | c.1733G>C p.G578A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1459310372, COSV101232129, COSV68372143; called by muse, mutect2
- CTSW | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100327485; called by muse, mutect2, varscan2
- CUBN | c.5343-1G>T p.X1781_splice | Splice Site (SNP) | VAF 20/154 reads (13%) | catalogued as COSV100913277; called by muse, mutect2, varscan2
- DAPK1 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1395566690, COSV63788856; called by muse, mutect2, varscan2
- DCDC1 | c.4112T>C p.L1371S (on ENST00000597505 / NM_001367979.1; = p.L478S on NM_020869.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100338630; called by muse, mutect2
- DCX | c.1030C>T p.R344W (on ENST00000636035 / NM_001195553.2; = p.R339W on NM_000555.3) | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57568676; called by muse, mutect2, varscan2
- DGKZ | c.1279G>A p.V427M (on ENST00000454345 / NM_001105540.2; = p.V239M on NM_003646.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs375795823; called by muse, mutect2, varscan2
- DISP1 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1299518659, COSV52659933; called by muse, mutect2, varscan2
- DNAI4 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs761215483, COSV64023518; called by muse, mutect2, varscan2
- DSEL | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1193014616, COSV100025960; called by muse, mutect2, varscan2
- DYNC2H1 | c.12296A>T p.K4099I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100519392; called by muse, mutect2, varscan2
- EPHA4 | c.1449G>C p.Q483H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99917246; called by muse, mutect2, varscan2
- ERBB4 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991337964, COSV53530091; called by muse, mutect2
- EYS | c.1759A>G p.R587G | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100676976; called by muse, mutect2, varscan2
- FNDC11 | c.323T>C p.F108S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100918825; called by muse, mutect2, varscan2
- GALNT18 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99925483; called by muse, mutect2, varscan2
- GLI3 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs145479568; called by muse, mutect2, varscan2
- GP5 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99757485; called by muse, mutect2, varscan2
- GUCA2B | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101001832; called by muse, mutect2, varscan2
- HOXA9 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777202871, COSV100604349; called by muse, mutect2, varscan2
- HTR2C | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194076654, COSV52220873; called by muse, mutect2, varscan2
- HTRA4 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100205872; called by muse, mutect2, varscan2
- IBTK | c.3202A>G p.T1068A | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1261291917, COSV100091242; called by muse, mutect2, varscan2
- IFNA7 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as COSV53332688; called by muse, mutect2, varscan2
- IGLJ3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.205); catalogued as rs367821564; called by muse, mutect2
- IQGAP3 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs771267264, COSV63250816; called by muse, mutect2, varscan2
- ITPR3 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100967877; called by muse, mutect2, varscan2
- KCNK7 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV100442331; called by muse, mutect2
- KCNT2 | c.301A>C p.S101R | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1410680251, COSV99654835, COSV99655778; called by muse, mutect2, varscan2
- KCTD1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs201089658, COSV58683148; called by muse, mutect2, varscan2
- KIF20A | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs144155991; called by muse, mutect2, varscan2
- KMT2A | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs782313746, COSV100629474; called by muse, mutect2
- LMBRD2 | c.2031T>G p.Y677* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99683128; called by muse, mutect2, varscan2
- LRRN2 | c.1634G>A p.W545* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100912923; called by muse, mutect2, varscan2
- MARK3 | c.33T>G p.N11K | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99358649; called by muse, mutect2, varscan2
- MYCBPAP | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV100088788; called by muse, mutect2, varscan2
- NBEA | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); catalogued as COSV100082916; called by muse, mutect2
- NF1 | c.3762C>A p.Y1254* | Nonsense Mutation (SNP) | VAF 142/251 reads (57%) | catalogued as CM071889, COSV100647932; called by muse, mutect2, varscan2
- NOTCH3 | c.5668A>G p.I1890V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1357741607, COSV99658373; called by muse, mutect2, varscan2
- NPAS4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs749039442, COSV100215172; called by muse, mutect2, varscan2
- NRXN1 | c.1798G>T p.A600S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs796052770, COSV100456355, COSV58437702; ClinVar: uncertain significance; called by muse, varscan2
- OR2T1 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.101); catalogued as COSV100822344; called by muse, mutect2, varscan2
- OR8H1 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100477277; called by muse, mutect2, varscan2
- OS9 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs11556568, COSV99223949; called by muse, mutect2, varscan2
- PCDH11X | c.3212G>C p.G1071A | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (1); PolyPhen possibly damaging (0.634); catalogued as COSV100014056; called by muse, mutect2, varscan2
- PCDH18 | c.1991C>G p.P664R | Missense Mutation (SNP) | VAF 79/143 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100787449; called by muse, mutect2, varscan2
- PCDHA8 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as COSV65325316; called by muse, mutect2, varscan2
- PCDHGA5 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs888571729, COSV54015754; called by muse, mutect2, varscan2
- PCDHGB1 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs752131601, COSV99543974; called by muse, mutect2
- PLA1A | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372028931; called by muse, mutect2
- PLPPR4 | c.1049T>C p.L350P | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV64567778; called by muse, mutect2, varscan2
- PPEF1 | c.1706C>A p.S569Y | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs375096082, COSV100583976; called by muse, mutect2, varscan2
- PRAMEF12 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100742977, COSV100743171; called by muse, mutect2, varscan2
- PRKAA2 | c.961G>C p.A321P | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV100983010; called by muse, mutect2, varscan2
- PRSS12 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99628676; called by muse, mutect2, varscan2
- PSTPIP1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs370965231; called by muse, mutect2, varscan2
- PTPN13 | c.6846C>A p.C2282* (on ENST00000411767 / NM_080683.3; = p.C2263* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 92/155 reads (59%) | catalogued as COSV100365242; called by muse, mutect2, varscan2
- PTPRZ1 | c.4289A>G p.D1430G | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV101100625; called by muse, mutect2, varscan2
- PYHIN1 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100932392; called by muse, mutect2, varscan2
- QRFPR | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs775342074, COSV57678770; called by muse, mutect2, varscan2
- RASEF | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 107/336 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100907022; called by muse, mutect2, varscan2
- RGS11 | c.736G>A p.V246I (on ENST00000397770 / NM_183337.3; = p.V225I on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs377094004, COSV51451467; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>G p.L448V (on ENST00000666250 / NM_001348490.2; = p.L256V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV51669105, COSV51676746; called by muse, mutect2
- RNF123 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1325961964, COSV100246693; called by muse, mutect2, varscan2
- RNFT2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1024413016, COSV99985463; called by muse, mutect2, varscan2
- ROS1 | c.2921C>T p.A974V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.467); catalogued as rs759586931, COSV63856269; called by muse, mutect2, varscan2
- RRP12 | c.3814C>T p.Q1272* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs1290033241, COSV100213379; called by muse, mutect2, varscan2
- RSPO1 | c.215T>A p.V72E | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100740665; called by muse, mutect2, varscan2
- SAGE1 | c.2238G>T p.E746D | Missense Mutation (SNP) | VAF 99/148 reads (67%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); catalogued as COSV100187706; called by muse, mutect2, varscan2
- SCN5A | c.5435C>T p.S1812L (on ENST00000333535 / NM_198056.3; = p.S1811L on NM_000335.5) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs371891414, CM031356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA4F | c.672C>T p.A224= | Splice Region (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100336101; called by muse, mutect2, varscan2
- SLC47A1 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 79/135 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV99565564; called by muse, mutect2, varscan2
- SLC4A2 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100055683; called by muse, mutect2, varscan2
- SP140 | c.406+2T>A p.X136_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100613960, COSV59452508; called by muse, mutect2, varscan2
- SPATA31A1 | c.3538del p.S1180Afs*14 | Frame Shift Del (DEL) | VAF 78/312 reads (25%) | catalogued as rs1185207322; called by mutect2, pindel, varscan2
- STAB1 | c.7091C>T p.T2364M | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.38); catalogued as rs199951449, COSV100195323; called by muse, mutect2, varscan2
- SYNE1 | c.13555G>A p.E4519K (on ENST00000367255 / NM_182961.4; = p.E4448K on NM_033071.3) | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs571224180, COSV55037210; called by muse, mutect2, varscan2
- TAF1L | c.3055C>A p.L1019M | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99645216; called by muse, mutect2, varscan2
- THOC7 | c.587C>G p.A196G | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1416138389, COSV99890115; called by muse, mutect2, varscan2
- TMEFF2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as rs376482759, COSV55829970; called by muse, mutect2, varscan2
- TMEM116 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759014592, COSV61391255; called by muse, mutect2, varscan2
- TMPRSS15 | c.3005G>C p.G1002A | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99518829; called by muse, mutect2, varscan2
- TP53BP1 | c.4376G>A p.R1459H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770333392, COSV99781158; called by muse, mutect2, varscan2
- TRPC6 | c.2044A>G p.I682V | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs1451821683, COSV100723734; called by muse, mutect2
- TRPV6 | c.2291A>G p.Q764R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100844391; called by muse, mutect2, varscan2
- ULK4 | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1283902876, COSV57215030; called by muse, mutect2, varscan2
- USP9X | c.2232C>G p.F744L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100199908; called by muse, mutect2, varscan2
- VIPAS39 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs766159848, COSV58938390; called by muse, mutect2, varscan2
- XPC | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs770955020, COSV99542527; called by muse, mutect2, varscan2
- ZBTB7A | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs773321856, COSV100475869; called by muse, mutect2, varscan2
- ZNF782 | c.1394T>G p.L465R | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100001565; called by muse, mutect2, varscan2
- ZP2 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV99559729; called by muse, mutect2, varscan2
- CETP | c.677del p.G226Efs*9 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.1342del p.R448Gfs*20 | Frame Shift Del (DEL) | VAF 45/118 reads (38%) | called by mutect2, pindel, varscan2
- MUC2 | c.2547C>A p.N849K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.45); called by muse, mutect2, varscan2
- TYW1 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- A1CF | c.1338C>A p.L446= (on ENST00000373993 / NM_138932.2; = p.L438= on NM_014576.4) | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV50957540, COSV50960654; called by muse, mutect2, varscan2
- ABTB2 | c.1524G>A p.E508= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs1408454286, COSV100131952; called by muse, mutect2, varscan2
- ADAM20 | c.903A>G p.K301= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV99833541; called by muse, mutect2, varscan2
- BMP10 | c.1041C>T p.Y347= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs557332981, COSV54894419; called by muse, mutect2, varscan2
- BRINP1 | c.327C>A p.G109= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99776484; called by muse, mutect2, varscan2
- CCDC157 | c.2214G>A p.R738= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99306663; called by muse, mutect2, varscan2
- COASY | c.900C>G p.R300= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99888657; called by muse, mutect2, varscan2
- COBLL1 | c.1770C>A p.G590= (on ENST00000392717; = p.G552= on NM_014900.5) | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV99528502; called by muse, varscan2
- DBH | c.1386C>T p.L462= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs1044818151, COSV101257135; called by muse, mutect2, varscan2
- DEFB121 | c.138T>C p.T46= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as COSV100889992, COSV66236473; called by muse, mutect2, varscan2
- DPP6 | c.381A>G p.Q127= (on ENST00000377770 / NM_001364500.2; = p.Q65= on NM_001936.5) | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs373192094; called by mutect2, varscan2
- DRG1 | c.762C>T p.S254= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100513744; called by muse, mutect2, varscan2
- DYNC2H1 | c.3871C>T p.L1291= | Silent (SNP) | VAF 19/286 reads (7%) | catalogued as COSV100519391; called by muse, mutect2
- FBF1 | c.117G>A p.A39= (on ENST00000586717; = p.A53= on NM_001319193.1) | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs767135992, COSV100045706, COSV59866914; called by muse, mutect2, varscan2
- GUCY1A1 | c.1002G>T p.T334= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV56654518, COSV99638573; called by muse, mutect2, varscan2
- HECW1 | c.3888G>A p.S1296= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as rs764833849, COSV67832225; called by muse, mutect2, varscan2
- KBTBD2 | c.1503T>C p.I501= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV100406565; called by muse, mutect2, varscan2
- KRT2 | c.852G>A p.T284= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as rs780098277, COSV59009938, COSV59013187; called by muse, mutect2, varscan2
- KRT6A | c.534C>T p.I178= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as rs773542280, COSV58103866; called by muse, mutect2, varscan2
- LONP1 | c.2658G>A p.T886= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs142397293, COSV100028401; called by muse, mutect2, varscan2
- MAP3K2 | c.576C>T p.F192= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1344545897, COSV100789376; called by muse, mutect2
- MITD1 | c.621T>A p.I207= | Silent (SNP) | VAF 79/164 reads (48%) | catalogued as COSV99175583; called by muse, mutect2, varscan2
- NR1I2 | c.90C>T p.N30= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs201105889, COSV61978725; called by muse, mutect2, varscan2
- NUP58 | c.1185A>G p.T395= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as COSV101098871; called by muse, mutect2
- PCDHA9 | c.1623C>T p.G541= | Silent (SNP) | VAF 67/152 reads (44%) | catalogued as COSV100969929; called by muse, mutect2, varscan2
- PCDHB1 | c.468C>T p.S156= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV60631585; called by muse, mutect2, varscan2
- PLA2R1 | c.2997C>T p.V999= | Silent (SNP) | VAF 81/141 reads (57%) | catalogued as rs758969986, COSV99323384; called by muse, mutect2, varscan2
- PPP6R3 | c.1416T>C p.T472= (on ENST00000393800 / NM_001352375.2; = p.T421= on NM_018312.5) | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99677176; called by muse, mutect2, varscan2
- RYR1 | c.2781G>A p.T927= | Silent (SNP) | VAF 73/106 reads (69%) | catalogued as rs762155957, COSV100616599; called by muse, mutect2, varscan2
- SH3PXD2B | c.2358C>T p.H786= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1307145198, COSV61128402; called by muse, mutect2, varscan2
- SIPA1L2 | c.2028C>T p.Y676= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs373874564; called by muse, mutect2, varscan2
- SLC5A4 | c.330G>A p.L110= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV99832083; called by muse, mutect2, varscan2
- STAC | c.615C>T p.F205= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as rs752252190, COSV56210826, COSV99830682; called by muse, mutect2, varscan2
- SYT16 | c.1542G>A p.S514= | Silent (SNP) | VAF 87/159 reads (55%) | catalogued as rs1027880448, COSV70860207; called by muse, mutect2, varscan2
- TACR3 | c.168C>T p.S56= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs1455891592, COSV59198200; called by muse, mutect2, varscan2
- TECTA | c.801T>A p.L267= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99881055; called by muse, mutect2, varscan2
- TGFBRAP1 | c.99C>T p.C33= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs1242727103, COSV99305369; called by muse, mutect2
- XRCC1 | c.516G>A p.Q172= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV99486666; called by muse, mutect2, varscan2
- ZBTB20 | c.1146C>T p.S382= (on ENST00000474710 / NM_001164342.2; = p.S309= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV61848520; called by muse, mutect2, varscan2
- ZNF521 | c.1467C>G p.L489= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100833047, COSV64125023; called by muse, mutect2, varscan2
- ZNF804A | c.3210T>C p.P1070= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100169467; called by muse, mutect2, varscan2
- AGAP7P | n.1652C>T | RNA (SNP) | VAF 33/195 reads (17%) | catalogued as rs374546426; called by muse, mutect2, varscan2
- GATA3 | c.*2G>C | 3'UTR (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100651159; called by muse, mutect2, varscan2
